Somatic mutation profile of tumor specimen 0DFDB8 from CCDI case PBBSBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.8 years (1,750 days).
Specimen 0DFDB8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 177bbf3d-4e44-44c4-8f4e-a84b3a2aa849.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFDAO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc6e2063-189d-4957-8893-0e9b2ac13e3a

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Intron 5, 3'UTR 4, 5'Flank 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 531/1865 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 414/1014 reads (41%) | catalogued as rs766011053, CM003945, CS001839, COSV62194781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 242/676 reads (36%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SOS1 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 563/1814 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397517154, CM070273, CM095735, CM116030, COSV67674782, COSV67675536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 30/824 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- C1QTNF1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 473/1025 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1287641888, COSV59260366; called by muse, mutect2, varscan2
- CFAP65 | c.1850A>G p.Q617R | Missense Mutation (SNP) | VAF 375/1173 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs141598128; called by muse, mutect2, varscan2
- MALRD1 | c.4027G>A p.D1343N | Missense Mutation (SNP) | VAF 391/866 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1040101031; called by muse, mutect2, varscan2
- PARP1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 253/645 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV64690089; called by muse, mutect2, varscan2
- TBC1D8 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 133/1058 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs758313344; called by muse, mutect2, varscan2
- ZMYND8 | c.1745C>T p.T582M (on ENST00000311275 / NM_001363741.2; = p.T602M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 524/1879 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs773983281, COSV53682171; called by muse, mutect2, varscan2
- ZNF469 | c.5525G>A p.G1842D (on ENST00000437464; = p.G1870D on NM_001367624.2) | Missense Mutation (SNP) | VAF 249/552 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.814); catalogued as rs1270184350; called by muse, mutect2, varscan2
- ANKRD20A4P | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 216/617 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CDKN2AIPNL | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 309/741 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DSCAML1 | c.4391T>A p.I1464N (on ENST00000321322; = p.I1404N on NM_020693.4) | Missense Mutation (SNP) | VAF 325/1088 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO36 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 28/594 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GABRE | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 568/650 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANK3 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 247/869 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KCNJ3 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 403/1361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLHL13 | c.50+1G>C p.X17_splice | Splice Site (SNP) | VAF 21/347 reads (6%) | called by muse, mutect2
- MDM1 | c.1927C>G p.R643G | Missense Mutation (SNP) | VAF 144/1720 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.194); called by muse, mutect2
- NALCN | c.1181T>G p.V394G | Missense Mutation (SNP) | VAF 336/1547 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR5T3 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 524/1701 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by mutect2, varscan2
- RBM4B | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 290/1010 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.334); called by mutect2, varscan2
- SPECC1 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 513/1070 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SYT9 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 325/1060 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- THOP1 | c.1630C>A p.Q544K | Missense Mutation (SNP) | VAF 192/670 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TP53BP1 | c.5585G>T p.W1862L | Missense Mutation (SNP) | VAF 58/815 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ADORA2A | c.648G>T p.L216= | Silent (SNP) | VAF 24/661 reads (4%) | called by muse, mutect2
- CATSPERD | c.1149C>T p.H383= | Silent (SNP) | VAF 236/897 reads (26%) | catalogued as rs369741473; called by muse, mutect2, varscan2
- IL2 | c.340C>T p.L114= | Silent (SNP) | VAF 275/694 reads (40%) | catalogued as COSV56985504; called by muse, mutect2, varscan2
- MEGF10 | c.345T>C p.H115= | Silent (SNP) | VAF 219/540 reads (41%) | called by muse, mutect2, varscan2
- MUC5B | c.8829C>A p.V2943= | Silent (SNP) | VAF 130/1113 reads (12%) | called by muse, mutect2, varscan2
- OR52B2 | c.777T>C p.F259= | Silent (SNP) | VAF 157/1338 reads (12%) | called by muse, mutect2, varscan2
- AGRN | c.3517-16C>T | Intron (SNP) | VAF 253/650 reads (39%) | called by muse, mutect2, varscan2
- B3GALT6 | c.*98G>A | 3'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- CABP1 | c.685+91G>T | Intron (SNP) | VAF 58/259 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.1783-23A>G | Intron (SNP) | VAF 194/412 reads (47%) | called by muse, mutect2, varscan2
- H1-5 | c.*50G>A | 3'UTR (SNP) | VAF 95/214 reads (44%) | called by muse, mutect2, varscan2
- MDGA2 | c.*25A>T | 3'UTR (SNP) | VAF 286/656 reads (44%) | catalogued as COSV62096943; called by muse, mutect2, varscan2
- MPV17 | c.279+27G>A | Intron (SNP) | VAF 244/750 reads (33%) | catalogued as rs374305348; called by muse, mutect2, varscan2
- MS4A18 | chr11:60729314 C>G | 5'Flank (SNP) | VAF 117/1153 reads (10%) | catalogued as rs779352723; called by muse, mutect2, varscan2
- MUC19 | n.13993C>T | RNA (SNP) | VAF 87/939 reads (9%) | catalogued as rs201260727; called by muse, mutect2
- PICK1 | c.*90T>A | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- ZC3H18 | c.1667+47G>A | Intron (SNP) | VAF 127/300 reads (42%) | catalogued as rs368749779; called by muse, mutect2
